Somatic mutation profile of tumor specimen C3L-05638-02 (aliquot CPT0346390006) from CPTAC case C3L-05638, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 77.0 years (28,112 days).
Specimen C3L-05638-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5634d079-b456-4ec1-a419-0358fff19d47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05638-32 (Blood Derived Normal), aliquot CPT0346420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bf31830-4115-4980-9e50-a606782e35b2

The open-access MAF lists 687 somatic variants for this specimen: 417 protein-altering or splice-affecting, 228 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 382, Silent 228, Intron 21, Nonsense Mutation 19, 5'Flank 8, Splice Region 7, RNA 5, Splice Site 4, Translation Start Site 4, 3'UTR 4, 5'UTR 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 286/459 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 286/459 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFTR | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 220/256 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs121908751, CM920143, CM940239, COSV50055904; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL2A1 | c.3275G>A p.G1092D | Missense Mutation (SNP) | VAF 172/426 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs794727684; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2744C>T p.S915F (on ENST00000272895 / NM_173076.3; = p.S597F on NM_015657.3) | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139223000; called by muse, mutect2, varscan2
- AC099489.1 | c.3766G>A p.G1256R | Missense Mutation (SNP) | VAF 148/377 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552010989; called by muse, mutect2, varscan2
- ACSM1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV54633527; called by muse, mutect2, varscan2
- ACSM2B | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61658175; called by muse, mutect2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 135/320 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, mutect2, varscan2
- ADAM29 | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 190/451 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100821942; called by muse, mutect2, varscan2
- ADCY5 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100568016; called by muse, mutect2, varscan2
- ADD1 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 228/586 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); catalogued as rs556312325, COSV53266719; called by muse, mutect2, varscan2
- ADGRF5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 95/258 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757471686, COSV51930071; called by muse, mutect2, varscan2
- ADH6 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 173/426 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs868358288; called by muse, mutect2, varscan2
- ADPRHL1 | c.4421G>A p.G1474E | Missense Mutation (SNP) | VAF 226/549 reads (41%) | SIFT tolerated, low confidence (0.2); catalogued as rs987809212; called by muse, mutect2, varscan2
- AHNAK2 | c.12017C>T p.S4006F | Missense Mutation (SNP) | VAF 307/653 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1478954776; called by muse, mutect2, varscan2
- AK9 | c.3533G>A p.R1178K | Missense Mutation (SNP) | VAF 95/130 reads (73%) | SIFT tolerated (0.42); PolyPhen benign (0.133); catalogued as COSV100394076; called by muse, mutect2, varscan2
- AMPD1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 155/371 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1344319121, COSV62416032; called by muse, mutect2, varscan2
- ANKRD11 | c.5773C>T p.P1925S | Missense Mutation (SNP) | VAF 228/328 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.795); catalogued as rs199914958; called by muse, mutect2, varscan2
- ANKRD24 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 212/588 reads (36%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.525); catalogued as rs778777281; called by muse, mutect2, varscan2
- ARGFX | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 127/384 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV100544240; called by muse, mutect2, varscan2
- ARHGAP31 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 168/403 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV51793184; called by muse, mutect2, varscan2
- ARHGEF28 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 319/546 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs766044075; called by muse, mutect2, varscan2
- ARMC4 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV53468445; called by muse, mutect2, varscan2
- ARSL | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 231/283 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs753447542; called by muse, mutect2, varscan2
- ASH1L | c.4520C>T p.S1507F | Missense Mutation (SNP) | VAF 183/606 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV64205605; called by muse, varscan2
- ASH1L | c.4408C>T p.P1470S | Missense Mutation (SNP) | VAF 158/615 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.159); catalogued as rs765907525; called by muse, varscan2
- ASS1 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 128/322 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV61690587; called by muse, mutect2, varscan2
- ASTN1 | c.3178C>T p.R1060C | Missense Mutation (SNP) | VAF 142/337 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs773275290, COSV62491574; called by muse, mutect2, varscan2
- ATP10A | c.1713C>A p.F571L | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63516875; called by muse, mutect2, varscan2
- ATP13A5 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV60868223; called by muse, mutect2, varscan2
- ATP8B4 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748152515, COSV52717553; called by muse, mutect2, varscan2
- AUTS2 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 715/1042 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs758102358, COSV61422736; called by muse, mutect2, varscan2
- BANK1 | c.1622G>A p.R541K | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV104403028, COSV59848376; called by muse, mutect2, varscan2
- BANK1 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs778946197; called by muse, mutect2, varscan2
- BEX5 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 125/168 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV61328416; called by muse, mutect2, varscan2
- BICD2 | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 214/526 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs556905704, COSV100794267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAT1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 370/649 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1462178379; called by muse, mutect2, varscan2
- C19orf81 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.768); catalogued as rs558395868; called by muse, mutect2, varscan2
- C5orf63 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 245/455 reads (54%) | SIFT deleterious, low confidence (0); catalogued as rs1299146562; called by muse, mutect2, varscan2
- CACNA1C | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59710283; called by muse, mutect2, varscan2
- CAPN5 | c.1649C>T p.S550F (on ENST00000456580; = p.S510F on NM_004055.5) | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1555042879; called by muse, mutect2, varscan2
- CCR2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 160/376 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as rs1391405321; called by muse, mutect2, varscan2
- CDH23 | c.8914G>A p.E2972K | Missense Mutation (SNP) | VAF 352/586 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs746716712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDHR2 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 209/695 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs1172914281; called by muse, mutect2, varscan2
- CETP | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.578); catalogued as COSV52362611; called by muse, mutect2, varscan2
- CFAP47 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 162/189 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52883269; called by muse, mutect2, varscan2
- CFAP54 | c.5807C>T p.A1936V | Missense Mutation (SNP) | VAF 93/217 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV61573794; called by muse, mutect2, varscan2
- CHL1 | c.2696G>A p.G899E (on ENST00000397491 / NM_001253387.1; = p.G915E on NM_006614.4) | Missense Mutation (SNP) | VAF 151/344 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56587040, COSV56601337; called by muse, mutect2, varscan2
- CHST1 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 280/675 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1487872504; called by muse, mutect2, varscan2
- CLCN7 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 182/445 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs1430982446; called by muse, mutect2, varscan2
- CLDN25 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 206/300 reads (69%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs745503566; called by muse, mutect2, varscan2
- CLEC16A | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 183/524 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1023839367; called by muse, mutect2, varscan2
- CLEC17A | c.200-1G>A p.X67_splice | Splice Site (SNP) | VAF 78/294 reads (27%) | catalogued as rs1568449955; called by muse, varscan2
- CLYBL | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 153/375 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1324325991; called by muse, mutect2, varscan2
- CMKLR1 | c.103G>A p.E35K (on ENST00000312143 / NM_001142344.2; = p.E33K on NM_004072.3) | Missense Mutation (SNP) | VAF 159/422 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV56438748; called by muse, mutect2, varscan2
- CRB1 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 130/360 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV66328805; called by muse, mutect2, varscan2
- CSMD1 | c.5429G>A p.R1810Q (on ENST00000520002; = p.R1809Q on NM_033225.6) | Missense Mutation (SNP) | VAF 98/131 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770980133, COSV59315770; called by muse, mutect2, varscan2
- CSNK1D | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 206/465 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs376492459, COSV53923694; called by muse, mutect2, varscan2
- CXCR2 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 230/552 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs759986280; called by muse, mutect2, varscan2
- CYLC2 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 162/410 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs746464948, COSV66336744; called by muse, mutect2, varscan2
- CYP1A2 | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 173/439 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.98); catalogued as COSV59661072; called by muse, mutect2, varscan2
- CYP2S1 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 142/354 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs775051633; called by muse, mutect2, varscan2
- DENND2A | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 133/684 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs201794849; called by muse, mutect2, varscan2
- DEUP1 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 83/111 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs542478848; called by muse, mutect2, varscan2
- DHRS9 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 149/352 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs201362566; called by muse, mutect2, varscan2
- DIP2C | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 129/362 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as rs368878837; called by muse, mutect2, varscan2
- DKK2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 171/372 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs918911009; called by muse, mutect2, varscan2
- DNAH12 | c.6962G>A p.R2321Q (on ENST00000351747; = p.R3189Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 105/328 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.038); catalogued as rs1198708530; called by muse, mutect2, varscan2
- DNAH8 | c.4730G>A p.R1577Q | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746134358, COSV104403137; called by muse, mutect2, varscan2
- DSCAM | c.5839C>T p.P1947S | Missense Mutation (SNP) | VAF 195/536 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs757616756; called by muse, mutect2, varscan2
- DSCAM | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as COSV68637955; called by muse, mutect2, varscan2
- DSG1 | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 163/427 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57137053; called by muse, mutect2, varscan2
- DSG4 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 157/415 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.112); catalogued as rs866537300, COSV57388550; called by muse, mutect2, varscan2
- DSTYK | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 138/350 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs868788895, COSV65688701; called by muse, mutect2, varscan2
- EDN3 | c.685C>T p.P229S (on ENST00000337938 / NM_001302455.2; = p.P215S on NM_207033.3) | Missense Mutation (SNP) | VAF 166/400 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs757559436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEPD1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 197/685 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.12); catalogued as rs1324187748, COSV54200048; called by muse, mutect2, varscan2
- EFCAB6 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 143/377 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs751191132; called by muse, mutect2, varscan2
- EFTUD2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 190/446 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770812734; called by muse, mutect2, varscan2
- EIF1AD | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 148/379 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.586); catalogued as rs201623056, COSV56463319, COSV56463762; called by muse, mutect2
- EMCN | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV56458221; called by muse, mutect2, varscan2
- EPB42 | c.490G>A p.G164S (on ENST00000441366 / NM_001114134.2; = p.G194S on NM_000119.3) | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55749873; called by muse, mutect2, varscan2
- EPHB6 | c.2757G>A p.M919I | Missense Mutation (SNP) | VAF 263/1112 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV63893387; called by muse, mutect2, varscan2
- EPS15L1 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 115/336 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs199975794; called by muse, mutect2, varscan2
- ERICH3 | c.1726+1G>A p.X576_splice | Splice Site (SNP) | VAF 99/264 reads (38%) | catalogued as rs1357930331; called by muse, mutect2, varscan2
- ETNPPL | c.618G>A p.K206= | Splice Region (SNP) | VAF 97/238 reads (41%) | catalogued as rs1205292863, COSV56595328; called by muse, mutect2, varscan2
- ETS2 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 107/266 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.201); catalogued as rs1280673132; called by muse, mutect2, varscan2
- FAM135B | c.3450G>A p.G1150= | Splice Region (SNP) | VAF 122/291 reads (42%) | catalogued as rs770702397; called by muse, mutect2, varscan2
- FAM181A | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 225/550 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs757033068; called by muse, mutect2, varscan2
- FBN2 | c.4417C>A p.R1473S | Missense Mutation (SNP) | VAF 372/431 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV52522869; called by muse, mutect2, varscan2
- FOXD4L3 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 92/494 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.178); catalogued as rs1206579861; called by muse, mutect2, varscan2
- FREM2 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 210/501 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779885596, COSV54842373; called by muse, mutect2, varscan2
- FRMPD2 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59721468; called by muse, mutect2, varscan2
- FRYL | c.6725C>T p.A2242V | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs1360371499, COSV99976162; called by muse, mutect2, varscan2
- GABRB2 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 288/540 reads (53%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.557); catalogued as COSV50903817; called by muse, mutect2, varscan2
- GKN1 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs777854722; called by muse, mutect2, varscan2
- GLRA2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 121/137 reads (88%) | SIFT tolerated (0.45); PolyPhen benign (0.131); catalogued as COSV54344147; called by muse, mutect2, varscan2
- GRK7 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 198/478 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV53825608; called by muse, mutect2, varscan2
- HACL1 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 201/523 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV100337433; called by muse, mutect2, varscan2
- HBP1 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 310/371 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99753595; called by muse, mutect2, varscan2
- HSP90AB1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 142/334 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV62336472; called by muse, varscan2
- HTR1F | c.995T>C p.L332S | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60389997; called by muse, mutect2, varscan2
- IGHV1-58 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 133/351 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs782314541; called by muse, mutect2, varscan2
- IGLON5 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 123/294 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as rs754919683; called by muse, mutect2, varscan2
- IL12RB1 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 164/409 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.131); catalogued as rs111662740; called by muse, mutect2, varscan2
- IL1F10 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as rs866046706; called by muse, mutect2, varscan2
- ILVBL | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs1333554660; called by muse, mutect2, varscan2
- INSRR | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 215/387 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1408545884; called by muse, mutect2, varscan2
- KBTBD6 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 138/389 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs748358631; called by muse, mutect2, varscan2
- KCNK10 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 197/474 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as COSV56641288; called by muse, mutect2, varscan2
- KCNK18 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 379/451 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100571966; called by muse, mutect2, varscan2
- KIAA1755 | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 176/445 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV54076332; called by muse, mutect2, varscan2
- KMT2D | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 322/751 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.191); catalogued as COSV56428443, COSV56486646; called by muse, mutect2, varscan2
- KRT34 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 203/505 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs773978057, COSV101222742; called by muse, mutect2, varscan2
- KRT76 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 131/314 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049857440; called by muse, varscan2
- LACRT | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 161/352 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.328); catalogued as COSV99143910; called by muse, mutect2, varscan2
- LGMN | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 156/367 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs771834504, COSV58405338; called by muse, mutect2, varscan2
- LRP1B | c.7543G>A p.E2515K | Missense Mutation (SNP) | VAF 111/275 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV67186894; called by muse, mutect2, varscan2
- LRRC31 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 146/348 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99246722; called by muse, mutect2, varscan2
- LTBP1 | c.2419G>A p.E807K (on ENST00000404816 / NM_206943.4; = p.E481K on NM_000627.4) | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.304); catalogued as COSV104417497; called by muse, mutect2, varscan2
- MAP3K21 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 113/279 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64041137; called by muse, mutect2, varscan2
- MAP7 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 260/353 reads (74%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs761615612, COSV100643883; called by muse, mutect2, varscan2
- MBD4 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as COSV51444625; called by muse, mutect2, varscan2
- METAP1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 116/279 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs532288032; called by muse, mutect2, varscan2
- MGAM | c.5444C>T p.S1815F | Missense Mutation (SNP) | VAF 576/851 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1052041192; called by muse, mutect2, varscan2
- MORC1 | c.1173C>T p.S391= | Splice Region (SNP) | VAF 100/227 reads (44%) | catalogued as rs200644565, COSV51713573; called by muse, mutect2, varscan2
- MOS | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs986716211; called by muse, mutect2, varscan2
- MROH5 | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as rs1274566992; called by muse, mutect2
- MRPL3 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs961023295; called by muse, mutect2, varscan2
- MRPS25 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 135/310 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs774371312, COSV53742503, COSV99507713; called by muse, mutect2, varscan2
- MRPS9 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99305792; called by muse, mutect2, varscan2
- MSR1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 144/167 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV50528827; called by muse, mutect2, varscan2
- MUC16 | c.43084C>T p.R14362* | Nonsense Mutation (SNP) | VAF 147/355 reads (41%) | catalogued as rs199911980; called by muse, mutect2, varscan2
- MUC16 | c.36476G>A p.R12159K | Missense Mutation (SNP) | VAF 159/402 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV67478327; called by muse, mutect2, varscan2
- MUC16 | c.16846G>A p.D5616N | Missense Mutation (SNP) | VAF 182/416 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV67492262; called by muse, mutect2, varscan2
- MYBPC3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 160/387 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs1247842104; called by muse, mutect2, varscan2
- MYO3A | c.4568G>A p.R1523Q | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs777250600, COSV56318222; called by muse, mutect2, varscan2
- MYO5B | c.1908C>T p.F636= | Splice Region (SNP) | VAF 99/286 reads (35%) | catalogued as rs1304631226, COSV53220064; called by muse, mutect2, varscan2
- MYPN | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 172/430 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62733103, COSV62738942; called by muse, mutect2, varscan2
- MYT1L | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 223/548 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as rs1430439055, COSV67720977; called by muse, varscan2
- MYT1L | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 193/451 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs1417204719; called by muse, mutect2, varscan2
- NAALAD2 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 140/199 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as rs760348318, COSV58959565; called by muse, mutect2, varscan2
- NEK5 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV62881021; called by muse, mutect2, varscan2
- NEXMIF | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 272/334 reads (81%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs974217155, COSV99281694; called by muse, mutect2, varscan2
- NLRC3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 219/538 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs776595528; called by muse, mutect2, varscan2
- NMNAT3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 133/356 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs774032862, COSV56158540; called by muse, mutect2, varscan2
- NOS1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs147820513, COSV57606244; called by muse, mutect2, varscan2
- NPY5R | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 131/312 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV100642971; called by muse, mutect2, varscan2
- NYAP2 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 208/476 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV56001359; called by muse, mutect2, varscan2
- OR11H6 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59643814; called by muse, mutect2, varscan2
- OR11L1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 151/434 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.803); catalogued as COSV104419167; called by muse, mutect2, varscan2
- OR1C1 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 129/341 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.533); catalogued as COSV68716413; called by muse, mutect2, varscan2
- OR1N2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 150/369 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV65460357; called by muse, mutect2, varscan2
- OR1R1P | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 136/340 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1350964237; called by mutect2, varscan2
- OR2A4 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 145/272 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV59575814; called by muse, mutect2, varscan2
- OR2T27 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100788275; called by mutect2, varscan2
- OR2W3 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 208/510 reads (41%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.996); catalogued as COSV64456954; called by muse, mutect2, varscan2
- OR4C15 | c.836G>A p.R279K (on ENST00000314644; = p.R225K on NM_001001920.2) | Missense Mutation (SNP) | VAF 171/404 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.044); catalogued as rs763560653, COSV58952052; called by muse, mutect2, varscan2
- OR4L1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 187/435 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs553802462, COSV59849023; called by muse, mutect2, varscan2
- OSBPL11 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 185/419 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs746090312; called by muse, mutect2, varscan2
- PAPSS1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 141/331 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1190978842, COSV54488263; called by muse, mutect2, varscan2
- PCDH18 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 187/427 reads (44%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as rs769506467; called by muse, mutect2, varscan2
- PCDH18 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 20/518 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61268410, COSV61268565; called by muse, mutect2
- PCDHA9 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 508/604 reads (84%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV65323219, COSV65326121; called by muse, varscan2
- PCDHB4 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 271/340 reads (80%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV52027024; called by muse, mutect2, varscan2
- PCNX1 | c.5132C>T p.S1711L | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53095111; called by muse, mutect2, varscan2
- PI4KA | c.4085C>T p.A1362V | Missense Mutation (SNP) | VAF 505/747 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV55404006; called by muse, mutect2, varscan2
- PIEZO2 | c.6852G>A p.R2284= | Splice Region (SNP) | VAF 102/225 reads (45%) | catalogued as COSV53286784; called by muse, mutect2, varscan2
- PLCB2 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 240/583 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs768671486; called by muse, mutect2, varscan2
- PLEKHB2 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 54/272 reads (20%) | PolyPhen benign (0); catalogued as COSV58230938; called by muse, mutect2, varscan2
- PPP1R1C | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 126/296 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV54718052; called by muse, mutect2, varscan2
- PPP4R4 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 134/317 reads (42%) | catalogued as rs1295955130, COSV58553355; called by muse, mutect2, varscan2
- PRAMEF17 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs3856325; called by muse, mutect2, varscan2
- PSG7 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 211/564 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.2); catalogued as COSV68445983; called by muse, mutect2, varscan2
- RGS3 | c.2420C>T p.P807L (on ENST00000350696 / NM_001282923.2; = p.P526L on NM_130795.4) | Missense Mutation (SNP) | VAF 263/609 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as rs747951736; called by muse, mutect2, varscan2
- RGS5 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 197/457 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100009101; called by muse, mutect2, varscan2
- RXRA | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 250/632 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1267488717; called by muse, mutect2, varscan2
- SATB1 | c.2216C>T p.T739I | Missense Mutation (SNP) | VAF 129/374 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV58670743; called by muse, mutect2, varscan2
- SERPINB12 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as rs745631830, COSV54033906; called by muse, mutect2, varscan2
- SIRPD | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 109/260 reads (42%) | PolyPhen possibly damaging (0.452); catalogued as rs767484756, COSV67547311; called by muse, mutect2, varscan2
- SLC1A2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 173/423 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99554733; called by muse, mutect2, varscan2
- SLC4A8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 123/324 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV60649535; called by muse, mutect2, varscan2
- SLX4 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 149/362 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781393524, CM136921, COSV99568341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNTG2 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 152/425 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57978984; called by muse, mutect2, varscan2
- SNTG2 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1246269519, COSV57998452; called by muse, mutect2
- SNX29 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs769080741; called by muse, mutect2, varscan2
- SPATA7 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 161/402 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs201038372; called by muse, mutect2, varscan2
- SPOCD1 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 176/456 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV57100480; called by muse, mutect2, varscan2
- SPTA1 | c.5644G>A p.G1882R | Missense Mutation (SNP) | VAF 136/450 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63749959, COSV63751396; called by muse, mutect2, varscan2
- SRGAP3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 117/299 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64531169, COSV64542042; called by muse, mutect2, varscan2
- STYXL2 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 183/443 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54807466; called by muse, mutect2, varscan2
- SYNE1 | c.22037C>T p.S7346L (on ENST00000367255 / NM_182961.4; = p.S7275L on NM_033071.3) | Missense Mutation (SNP) | VAF 83/124 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1397830818, COSV99585998; called by muse, mutect2, varscan2
- SYNM | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 172/369 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as rs782381550; called by muse, mutect2, varscan2
- TAF3 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 160/383 reads (42%) | catalogued as COSV60210796; called by muse, mutect2, varscan2
- TBC1D10B | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 260/680 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs111973642; called by muse, mutect2, varscan2
- TBC1D13 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 132/318 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56355804; called by muse, mutect2, varscan2
- TEKT1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as COSV58622664; called by muse, mutect2, varscan2
- TENM3 | c.5650G>A p.D1884N | Missense Mutation (SNP) | VAF 143/393 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs200581858, COSV69314507; called by muse, mutect2, varscan2
- TEX44 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 198/556 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs1227925519; called by muse, mutect2
- TFRC | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs137978255; called by muse, mutect2, varscan2
- THADA | c.5083C>T p.P1695S | Missense Mutation (SNP) | VAF 154/347 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs773079245, COSV57687684; called by muse, mutect2, varscan2
- THEMIS | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 215/285 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV64072316; called by muse, mutect2, varscan2
- THRB | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 108/312 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM091605, CM900208, CP015819, COSV54979728; called by muse, mutect2, varscan2
- TIE1 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 151/396 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468702120; called by muse, varscan2
- TINAG | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs867360066, COSV52507137; called by muse, mutect2, varscan2
- TMC7 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 170/425 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV100432815; called by muse, mutect2, varscan2
- TMCO5A | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as COSV60463872, COSV60465330; called by muse, mutect2, varscan2
- TMED3 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 163/404 reads (40%) | catalogued as rs539915664, COSV55302391; called by muse, mutect2, varscan2
- TMEM176B | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 125/662 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs772939068, COSV58439716; called by muse, mutect2, varscan2
- TNFRSF13B | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs1000091022; called by muse, mutect2, varscan2
- TNR | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as rs1001407974, COSV54877336; called by muse, mutect2, varscan2
- TNR | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 255/559 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as rs1245465561, COSV54887052; called by muse, mutect2, varscan2
- TOPAZ1 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59064734; called by muse, mutect2, varscan2
- TRAF3IP3 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV50559305, COSV99161778; called by muse, mutect2, varscan2
- TRBV2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 327/539 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs1237159000; called by muse, mutect2, varscan2
- TTC21A | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 181/448 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs1363182440; called by muse, mutect2, varscan2
- USP29 | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 151/410 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1452380581, COSV54237375; called by muse, mutect2, varscan2
- VEPH1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 187/437 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62879045; called by muse, mutect2, varscan2
- WDR81 | c.5545C>T p.H1849Y (on ENST00000409644 / NM_001163809.2; = p.H798Y on NM_152348.4) | Missense Mutation (SNP) | VAF 145/363 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.498); catalogued as rs1302317133, COSV100488373; called by muse, mutect2, varscan2
- ZAN | c.5209G>A p.A1737T | Missense Mutation (SNP) | VAF 268/311 reads (86%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs201112870; called by muse, mutect2, varscan2
- ZNF304 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 185/492 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs553719465, COSV56584305; called by muse, mutect2, varscan2
- ZNF317 | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV56111664; called by muse, mutect2, varscan2
- ZNF469 | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 252/343 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs1212528979; called by muse, mutect2, varscan2
- ZNF479 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 94/431 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58643190; called by muse, mutect2, varscan2
- ZNF485 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 157/435 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV100700188; called by muse, mutect2, varscan2
- ZNF717 | c.2417G>A p.R806K | Missense Mutation (SNP) | VAF 152/388 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.323); catalogued as COSV101277514; called by muse, mutect2, varscan2
- ZNF750 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 197/472 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs192308712; called by muse, mutect2, varscan2
- ZNF804A | c.2413C>T p.P805S | Missense Mutation (SNP) | VAF 159/379 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs201018507; called by muse, mutect2, varscan2
- ZNF835 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 212/520 reads (41%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.985); catalogued as COSV73379305; called by muse, mutect2, varscan2
- ZPLD1 | c.395G>A p.G132E (on ENST00000466937 / NM_001329788.1; = p.G148E on NM_175056.2) | Missense Mutation (SNP) | VAF 150/395 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60354034; called by muse, mutect2, varscan2
- ACE | c.3713C>T p.P1238L | Missense Mutation (SNP) | VAF 180/521 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM12 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 271/343 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ADAM17 | c.2462A>T p.E821V | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ADGRF5 | c.2407C>T p.L803F | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ADH1B | c.60del p.K20Nfs*25 | Frame Shift Del (DEL) | VAF 147/427 reads (34%) | called by mutect2, pindel, varscan2
- ADHFE1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 163/408 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AGR2 | c.355T>A p.S119T | Missense Mutation (SNP) | VAF 153/509 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AKR1C4 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ANKRD24 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 334/781 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ANO4 | c.1009G>A p.D337N (on ENST00000392977 / NM_001286615.2; = p.D302N on NM_178826.4) | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANO9 | c.1380G>A p.W460* | Nonsense Mutation (SNP) | VAF 219/531 reads (41%) | called by muse, mutect2, varscan2
- ANTXR1 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP29 | c.3266G>A p.S1089N | Missense Mutation (SNP) | VAF 186/473 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCORL1 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 285/356 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIRC3 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 179/251 reads (71%) | SIFT tolerated (0.71); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BRD3 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 117/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C2 | c.2252C>T p.P751L | Missense Mutation (SNP) | VAF 144/370 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CACNA1B | c.497G>A p.W166* | Nonsense Mutation (SNP) | VAF 108/339 reads (32%) | called by muse, mutect2, varscan2
- CAMKV | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 142/375 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- CAPN7 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARD11 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 356/623 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CBL | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 124/169 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC144A | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 125/343 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CCDC178 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CDC20B | c.1547G>A p.W516* (on ENST00000381375 / NM_001170402.1; = p.W512* on NM_152623.2) | Nonsense Mutation (SNP) | VAF 87/393 reads (22%) | called by muse, mutect2, varscan2
- CFAP221 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 157/414 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFHR5 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CHKB | c.1096A>T p.I366L | Missense Mutation (SNP) | VAF 159/383 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CLCN2 | c.23A>C p.E8A | Missense Mutation (SNP) | VAF 203/458 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLP1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 237/534 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 147/796 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- CPNE9 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 124/375 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2
- CRYBG3 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 210/488 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CYB5R2 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 145/387 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CYFIP2 | c.3535G>A p.D1179N (on ENST00000616178 / NM_001291722.2; = p.D1154N on NM_014376.4) | Missense Mutation (SNP) | VAF 187/219 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DACH1 | c.1787G>A p.G596E (on ENST00000619232 / NM_001366712.1; = p.G342E on NM_004392.6) | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DCST1 | c.1656G>A p.W552* | Nonsense Mutation (SNP) | VAF 351/601 reads (58%) | called by muse, varscan2
- DEF8 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 148/203 reads (73%) | SIFT tolerated (0.66); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- DENND1A | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 176/444 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DHX16 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 264/667 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIP2C | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMBT1 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 476/564 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DNAH1 | c.7958T>G p.F2653C | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- DNAH10 | c.8686G>A p.E2896K (on ENST00000409039; = p.E2835K on NM_207437.3) | Missense Mutation (SNP) | VAF 176/419 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DNAH5 | c.11878G>A p.D3960N | Missense Mutation (SNP) | VAF 92/124 reads (74%) | SIFT tolerated (0.9); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DOCK3 | c.5009C>T p.P1670L | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- EBF2 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 113/155 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ECM2 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFCAB3 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 114/291 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF4G2 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ELOVL5 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- EMG1 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ENTR1 | c.419C>T p.S140F (on ENST00000357365 / NM_001039707.2; = p.S117F on NM_006643.4) | Missense Mutation (SNP) | VAF 131/310 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- EPPK1 | c.5845C>T p.L1949F | Missense Mutation (SNP) | VAF 214/522 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- EPS15L1 | c.2357C>T p.P786L | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERICH3 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ESYT1 | c.2270C>T p.P757L | Missense Mutation (SNP) | VAF 199/472 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ETV6 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 189/479 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FAM227A | c.223C>T p.L75= | Splice Region (SNP) | VAF 84/255 reads (33%) | called by muse, mutect2, varscan2
- FAT1 | c.11621C>T p.T3874I | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FCRL2 | c.1202T>G p.V401G | Missense Mutation (SNP) | VAF 149/538 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.2528G>A p.G843E | Missense Mutation (SNP) | VAF 207/776 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FSIP2 | c.6065G>A p.R2022K | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- GPR55 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 131/322 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC9 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 171/505 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- IL10RA | c.389T>G p.V130G | Missense Mutation (SNP) | VAF 111/166 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL1RL1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 152/429 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IRF2 | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KALRN | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 190/434 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM7A | c.2468G>A p.R823K | Missense Mutation (SNP) | VAF 108/456 reads (24%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.4685G>A p.G1562E | Missense Mutation (SNP) | VAF 130/156 reads (83%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, varscan2
- KIAA1217 | c.4015G>T p.E1339* | Nonsense Mutation (SNP) | VAF 147/388 reads (38%) | called by muse, mutect2, varscan2
- KIAA1522 | c.215C>T p.S72F (on ENST00000373480 / NM_001198972.2; = p.S131F on NM_020888.3) | Missense Mutation (SNP) | VAF 161/392 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KLRF2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 86/239 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2C | c.14674G>A p.D4892N | Missense Mutation (SNP) | VAF 108/482 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2D | c.7778C>T p.P2593L | Missense Mutation (SNP) | VAF 231/641 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- KRT24 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 176/433 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP4-1 | c.403A>G p.T135A (on ENST00000398472; = p.T116A on NM_033060.3) | Missense Mutation (SNP) | VAF 195/476 reads (41%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- LAT2 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 286/500 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LILRA1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 236/578 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- LMAN1L | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 187/467 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXHD1 | c.4816G>A p.A1606T | Missense Mutation (SNP) | VAF 184/487 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- LPAR5 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 233/557 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC4 | c.1702A>C p.I568L | Missense Mutation (SNP) | VAF 557/841 reads (66%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LRTM1 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 174/447 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LY6H | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 300/729 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- MAGI1 | c.1574C>T p.T525I | Missense Mutation (SNP) | VAF 134/319 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAN2A2 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MARCO | c.118A>G p.N40D | Missense Mutation (SNP) | VAF 118/306 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MBOAT4 | c.734G>A p.W245* | Nonsense Mutation (SNP) | VAF 152/219 reads (69%) | called by muse, mutect2, varscan2
- MEGF8 | c.4237G>T p.G1413W (on ENST00000251268 / NM_001271938.2; = p.G1346W on NM_001410.3) | Missense Mutation (SNP) | VAF 206/573 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MICAL3 | c.2908C>T p.H970Y | Missense Mutation (SNP) | VAF 238/615 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, varscan2
- MINAR2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 189/241 reads (78%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MKI67 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 341/405 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MLXIPL | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 206/492 reads (42%) | called by muse, mutect2, varscan2
- MMP10 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 122/177 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MNDA | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 162/566 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MON1B | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 192/247 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MRC2 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 180/417 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH9 | c.2398A>T p.I800L | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MRPL3 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 102/271 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC16 | c.40249C>T p.Q13417* | Nonsense Mutation (SNP) | VAF 133/333 reads (40%) | called by muse, mutect2, varscan2
- MUC16 | c.40248C>A p.S13416R | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MYCBP2 | c.13883C>T p.A4628V (on ENST00000357337; = p.A4666V on NM_015057.5) | Missense Mutation (SNP) | VAF 167/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MYF6 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 220/580 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- MYO7A | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 159/441 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCAM1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 185/253 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFAF6 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 76/208 reads (37%) | called by muse, mutect2, varscan2
- NID2 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 187/453 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NKX2-2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 235/618 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOVA2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.027); called by muse, varscan2
- NPIPB9 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR2C2 | c.575A>T p.K192M (on ENST00000393102; = p.K211M on NM_003298.5) | Missense Mutation (SNP) | VAF 106/285 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OBSCN | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 229/487 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- OPN5 | c.832G>T p.G278* | Nonsense Mutation (SNP) | VAF 174/415 reads (42%) | called by muse, mutect2, varscan2
- P4HTM | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 232/583 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PAK2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PAPPA | c.1178G>A p.W393* | Nonsense Mutation (SNP) | VAF 220/504 reads (44%) | called by muse, mutect2, varscan2
- PAPPA | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 222/480 reads (46%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- PARM1 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 224/511 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PFKFB3 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 94/226 reads (42%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3C2G | c.2192C>T p.S731F (on ENST00000676171; = p.S690F on NM_004570.5) | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, varscan2
- PKDREJ | c.6425C>T p.S2142F | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.233); called by muse, mutect2
- PKHD1L1 | c.8971C>T p.P2991S | Missense Mutation (SNP) | VAF 129/352 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLPPR3 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 153/417 reads (37%) | called by muse, mutect2, varscan2
- PNMA8C | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- POC1A | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 134/334 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- POLR2M | c.964-1G>A p.X322_splice | Splice Site (SNP) | VAF 129/266 reads (48%) | called by muse, mutect2, varscan2
- POTEA | c.1238C>T p.S413L (on ENST00000519951 / NM_001005365.2; = p.S367L on NM_001002920.1) | Missense Mutation (SNP) | VAF 135/341 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- PRAMEF10 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, varscan2
- PRAMEF18 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 148/686 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTER | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN20 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- QARS1 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 170/453 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- RAD17 | c.464G>A p.G155D (on ENST00000380774 / NM_133339.2; = p.G144D on NM_002873.1) | Missense Mutation (SNP) | VAF 328/545 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RANBP2 | c.4174G>T p.E1392* | Nonsense Mutation (SNP) | VAF 200/474 reads (42%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 71/464 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- RIMS4 | c.487A>C p.I163L | Missense Mutation (SNP) | VAF 152/344 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- RORB | c.799G>A p.E267K (on ENST00000396204 / NM_001365023.1; = p.E256K on NM_006914.4) | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- RP1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 132/384 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2
- RPL3L | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 133/342 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SCN4A | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 180/420 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SDR16C5 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 122/349 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SH3TC1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 176/475 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SIPA1L1 | c.1821G>A p.L607= | Splice Region (SNP) | VAF 89/263 reads (34%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 146/386 reads (38%) | called by muse, mutect2, varscan2
- SKA1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 170/419 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC22A12 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 235/328 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC25A12 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 135/335 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SLC30A8 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 166/390 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SLC34A1 | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 123/394 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 140/357 reads (39%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- SPEF2 | c.5392A>T p.I1798F | Missense Mutation (SNP) | VAF 112/165 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SPEM2 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 189/542 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- SPRR1A | c.179A>G p.K60R | Missense Mutation (SNP) | VAF 567/1075 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2
- SSU72P2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 71/531 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- STAB2 | c.2698G>A p.G900S | Missense Mutation (SNP) | VAF 182/427 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STBD1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 190/443 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- STK31 | c.2990A>G p.E997G | Missense Mutation (SNP) | VAF 309/538 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- STXBP5L | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 159/384 reads (41%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- STYXL2 | c.1460T>A p.I487N | Missense Mutation (SNP) | VAF 194/582 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- SULT4A1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 163/463 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- SVOPL | c.1241C>G p.T414S (on ENST00000419765; = p.T262S on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/596 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TAOK2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 130/285 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TARM1 | c.94+1G>A p.X32_splice (on ENST00000616041 / NM_001330650.1; = p.X24_splice on NM_001135686.3) | Splice Site (SNP) | VAF 193/512 reads (38%) | called by muse, mutect2, varscan2
- TARM1 | c.94G>A p.G32R (on ENST00000616041 / NM_001330650.1; = p.G24R on NM_001135686.3) | Missense Mutation (SNP) | VAF 196/516 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS1R2 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 119/317 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TBC1D8 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 160/398 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM2 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- TERF2 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 189/471 reads (40%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TEX26 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 173/413 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- THSD4 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 191/450 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM151B | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 223/509 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TOPAZ1 | c.3631A>G p.T1211A | Missense Mutation (SNP) | VAF 92/281 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOX3 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 183/467 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TRAJ36 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 106/272 reads (39%) | called by muse, mutect2, varscan2
- TRANK1 | c.6221G>A p.G2074E | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC5 | c.1417C>G p.H473D | Missense Mutation (SNP) | VAF 149/193 reads (77%) | SIFT tolerated (1); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- TRPC5 | c.1416G>A p.W472* | Nonsense Mutation (SNP) | VAF 149/191 reads (78%) | called by muse, mutect2, varscan2
- TRPC7 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 237/289 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- UBQLNL | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 174/426 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- UGT2A3 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 161/403 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- WT1 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 114/273 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ZFP28 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF282 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 147/634 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.364); called by muse, varscan2
- ZNF334 | c.404A>T p.K135I | Missense Mutation (SNP) | VAF 151/364 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ZNF579 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 262/606 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ABCB1 | c.909C>T p.F303= | Silent (SNP) | VAF 175/628 reads (28%) | catalogued as COSV55956819; called by muse, mutect2, varscan2
- ACADVL | c.225G>T p.V75= | Silent (SNP) | VAF 142/373 reads (38%) | called by muse, mutect2, varscan2
- ACSM1 | c.684G>A p.G228= | Silent (SNP) | VAF 165/426 reads (39%) | catalogued as rs1172274719, COSV54635725; called by muse, mutect2, varscan2
- ACTR3B | c.645C>T p.I215= | Silent (SNP) | VAF 312/656 reads (48%) | called by muse, mutect2, varscan2
- ADAM28 | c.1125C>T p.F375= | Silent (SNP) | VAF 93/137 reads (68%) | called by muse, mutect2, varscan2
- ADGRL4 | c.33C>T p.S11= | Silent (SNP) | VAF 75/242 reads (31%) | catalogued as rs1480498804, COSV66061384, COSV66062028; called by muse, mutect2, varscan2
- ADH1C | c.585C>T p.T195= | Silent (SNP) | VAF 155/377 reads (41%) | catalogued as rs761307510; called by muse, mutect2, varscan2
- ADPRHL1 | c.4422G>A p.G1474= | Silent (SNP) | VAF 224/550 reads (41%) | called by muse, mutect2, varscan2
- AEBP1 | c.3129C>T p.T1043= | Silent (SNP) | VAF 534/932 reads (57%) | called by muse, mutect2, varscan2
- AGTR1 | c.810C>T p.I270= | Silent (SNP) | VAF 168/371 reads (45%) | catalogued as COSV100837199; called by muse, mutect2, varscan2
- AJAP1 | c.735G>A p.R245= | Silent (SNP) | VAF 224/500 reads (45%) | called by muse, varscan2
- ALAS2 | c.933G>A p.K311= | Silent (SNP) | VAF 198/237 reads (84%) | catalogued as rs746627894, COSV100238556, COSV58189379; called by muse, mutect2, varscan2
- ALPK3 | c.3567C>T p.P1189= | Silent (SNP) | VAF 196/515 reads (38%) | called by muse, mutect2, varscan2
- AMOT | c.1068C>T p.F356= | Silent (SNP) | VAF 285/347 reads (82%) | called by muse, mutect2, varscan2
- ANK3 | c.3207C>A p.S1069= (on ENST00000280772 / NM_001320874.2; = p.S203= on NM_001149.3) | Silent (SNP) | VAF 111/290 reads (38%) | called by muse, mutect2, varscan2
- ANKRD55 | c.1338C>T p.F446= | Silent (SNP) | VAF 412/721 reads (57%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.963C>T p.H321= | Silent (SNP) | VAF 133/348 reads (38%) | catalogued as rs369264614; called by muse, mutect2, varscan2
- ATP13A4 | c.1587G>A p.A529= | Silent (SNP) | VAF 225/538 reads (42%) | catalogued as rs778053692, COSV55066194; called by muse, mutect2, varscan2
- BPIFC | c.663C>T p.T221= | Silent (SNP) | VAF 114/141 reads (81%) | called by muse, mutect2, varscan2
- BRINP1 | c.33C>T p.F11= | Silent (SNP) | VAF 121/343 reads (35%) | catalogued as COSV56300484; called by muse, mutect2, varscan2
- C7 | c.456G>A p.R152= | Silent (SNP) | VAF 123/172 reads (72%) | called by muse, mutect2, varscan2
- CACNA1E | c.2655C>T p.A885= | Silent (SNP) | VAF 213/529 reads (40%) | catalogued as COSV62398571; called by muse, mutect2, varscan2
- CAMK1G | c.945C>T p.H315= | Silent (SNP) | VAF 148/389 reads (38%) | catalogued as COSV99152356; called by muse, mutect2, varscan2
- CARD17 | c.261G>T p.L87= | Silent (SNP) | VAF 90/140 reads (64%) | called by muse, mutect2
- CARD6 | c.987C>T p.F329= | Silent (SNP) | VAF 191/271 reads (70%) | catalogued as COSV54568678; called by muse, mutect2, varscan2
- CASC3 | c.333C>T p.S111= | Silent (SNP) | VAF 118/314 reads (38%) | catalogued as rs1193486516; called by muse, mutect2, varscan2
- CBY2 | c.573G>A p.K191= | Silent (SNP) | VAF 222/473 reads (47%) | catalogued as rs371332004; called by muse, mutect2, varscan2
- CCDC141 | c.4581C>T p.L1527= | Silent (SNP) | VAF 70/205 reads (34%) | catalogued as rs1230024365; called by muse, mutect2, varscan2
- CCDC154 | c.1500C>T p.A500= | Silent (SNP) | VAF 136/343 reads (40%) | catalogued as rs1314840131, COSV66736671; called by muse, mutect2, varscan2
- CCDC88B | c.2229C>T p.A743= | Silent (SNP) | VAF 196/278 reads (71%) | called by muse, mutect2, varscan2
- CCS | c.333G>A p.E111= | Silent (SNP) | VAF 205/467 reads (44%) | called by muse, mutect2, varscan2
- CD14 | c.1038C>T p.S346= | Silent (SNP) | VAF 205/518 reads (40%) | catalogued as COSV57371387; called by muse, mutect2, varscan2
- CD300LB | c.48C>T p.F16= | Silent (SNP) | VAF 104/321 reads (32%) | called by muse, mutect2, varscan2
- CDH2 | c.2563C>T p.L855= | Silent (SNP) | VAF 142/337 reads (42%) | called by mutect2, varscan2
- CDHR2 | c.2208G>A p.G736= | Silent (SNP) | VAF 209/694 reads (30%) | called by muse, mutect2, varscan2
- CDHR2 | c.2484G>A p.V828= | Silent (SNP) | VAF 467/771 reads (61%) | catalogued as rs765840433; called by muse, mutect2, varscan2
- CEACAM18 | c.564G>A p.K188= | Silent (SNP) | VAF 146/405 reads (36%) | called by muse, mutect2, varscan2
- CFAP54 | c.6042G>A p.K2014= | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as rs760394350, COSV61571319, COSV61571934; called by muse, mutect2, varscan2
- CFAP58 | c.2001G>A p.G667= | Silent (SNP) | VAF 313/369 reads (85%) | called by muse, mutect2, varscan2
- CGN | c.2352C>T p.S784= | Silent (SNP) | VAF 475/767 reads (62%) | called by muse, mutect2, varscan2
- CHID1 | c.34C>T p.L12= | Silent (SNP) | VAF 172/408 reads (42%) | catalogued as rs373565045; called by muse, mutect2, varscan2
- CLN3 | c.819C>T p.F273= (on ENST00000360019 / NM_001286104.2; = p.F297= on NM_000086.2) | Silent (SNP) | VAF 162/425 reads (38%) | catalogued as COSV61104957; called by muse, mutect2, varscan2
- CLSTN1 | c.1308T>A p.S436= (on ENST00000377298 / NM_001009566.3; = p.S426= on NM_014944.4) | Silent (SNP) | VAF 148/353 reads (42%) | called by muse, mutect2, varscan2
- CMSS1 | c.366C>T p.F122= | Silent (SNP) | VAF 89/258 reads (34%) | called by muse, mutect2, varscan2
- CNR2 | c.555G>A p.L185= | Silent (SNP) | VAF 212/515 reads (41%) | called by muse, mutect2, varscan2
- COL14A1 | c.873C>T p.A291= | Silent (SNP) | VAF 103/286 reads (36%) | called by muse, mutect2, varscan2
- COL7A1 | c.8289C>A p.G2763= | Silent (SNP) | VAF 148/388 reads (38%) | called by muse, mutect2, varscan2
- COLEC12 | c.429G>A p.G143= | Silent (SNP) | VAF 185/429 reads (43%) | catalogued as rs752132137; called by muse, mutect2, varscan2
- CORO1B | c.876C>T p.I292= | Silent (SNP) | VAF 148/201 reads (74%) | catalogued as COSV100396520; called by muse, mutect2, varscan2
- CPNE9 | c.879G>A p.K293= | Silent (SNP) | VAF 125/376 reads (33%) | called by muse, mutect2
- CSMD1 | c.3609C>T p.D1203= (on ENST00000520002; = p.D1202= on NM_033225.6) | Silent (SNP) | VAF 115/171 reads (67%) | called by muse, mutect2, varscan2
- CSNK1E | c.744C>T p.F248= | Silent (SNP) | VAF 118/278 reads (42%) | called by muse, mutect2, varscan2
- CUBN | c.6801C>T p.F2267= | Silent (SNP) | VAF 130/314 reads (41%) | catalogued as rs542353518, COSV64714149; called by muse, mutect2, varscan2
- DBH | c.405G>A p.Q135= | Silent (SNP) | VAF 181/483 reads (37%) | called by muse, mutect2, varscan2
- DCHS2 | c.1470C>T p.F490= | Silent (SNP) | VAF 222/624 reads (36%) | catalogued as COSV59719266; called by muse, mutect2
- DDX53 | c.903C>A p.V301= | Silent (SNP) | VAF 175/218 reads (80%) | catalogued as rs1238031295, COSV100028774; called by muse, mutect2, varscan2
- DNAH14 | c.3633A>G p.L1211= | Silent (SNP) | VAF 174/432 reads (40%) | catalogued as rs559153394; called by muse, mutect2, varscan2
- DPYD | c.3063G>A p.V1021= | Silent (SNP) | VAF 99/269 reads (37%) | called by muse, mutect2, varscan2
- DSCAM | c.3585G>A p.V1195= | Silent (SNP) | VAF 130/311 reads (42%) | called by muse, mutect2, varscan2
- DSTYK | c.2748C>T p.S916= | Silent (SNP) | VAF 148/369 reads (40%) | called by muse, mutect2, varscan2
- ELMO1 | c.588G>A p.S196= | Silent (SNP) | VAF 159/512 reads (31%) | catalogued as rs867262486, COSV60299505, COSV60302268; called by muse, mutect2, varscan2
- EP400 | c.3873C>T p.R1291= | Silent (SNP) | VAF 148/444 reads (33%) | called by muse, mutect2, varscan2
- EREG | c.509G>A p.*170= | Silent (SNP) | VAF 127/327 reads (39%) | called by muse, mutect2, varscan2
- ERICH3 | c.2691G>A p.Q897= | Silent (SNP) | VAF 219/504 reads (43%) | catalogued as rs749890558, COSV100445038, COSV58607243; called by muse, mutect2, varscan2
- ESPL1 | c.5427C>T p.S1809= | Silent (SNP) | VAF 204/496 reads (41%) | called by muse, mutect2, varscan2
- EZH1 | c.897C>T p.C299= | Silent (SNP) | VAF 166/423 reads (39%) | called by muse, mutect2, varscan2
- EZHIP | c.1281G>A p.E427= | Silent (SNP) | VAF 230/276 reads (83%) | called by muse, mutect2, varscan2
- FAM170B | c.165G>A p.R55= | Silent (SNP) | VAF 228/526 reads (43%) | called by muse, mutect2
- FAM236C | c.105G>T p.A35= | Silent (SNP) | VAF 101/270 reads (37%) | called by muse, mutect2, varscan2
- FASLG | c.225G>A p.G75= | Silent (SNP) | VAF 279/718 reads (39%) | called by muse, mutect2, varscan2
- FCGR2A | c.159C>T p.L53= (on ENST00000271450 / NM_001136219.3; = p.L52= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 222/729 reads (30%) | called by muse, mutect2, varscan2
- FCRL2 | c.1155C>T p.S385= | Silent (SNP) | VAF 194/329 reads (59%) | called by muse, mutect2, varscan2
- FGFR2 | c.1470T>C p.G490= | Silent (SNP) | VAF 274/330 reads (83%) | called by muse, mutect2, varscan2
- FGG | c.465C>T p.A155= | Silent (SNP) | VAF 184/407 reads (45%) | catalogued as rs753041046, CD1515063, COSV60194777; called by muse, mutect2, varscan2
- FILIP1 | c.1953G>A p.G651= | Silent (SNP) | VAF 146/202 reads (72%) | catalogued as COSV52728618; called by muse, mutect2, varscan2
- GABRB2 | c.897C>A p.I299= | Silent (SNP) | VAF 290/542 reads (54%) | called by muse, mutect2, varscan2
- GDF5 | c.144G>A p.K48= | Silent (SNP) | VAF 253/601 reads (42%) | called by muse, mutect2, varscan2
- GGT7 | c.528C>T p.I176= | Silent (SNP) | VAF 178/436 reads (41%) | catalogued as rs774421001, COSV60539725; called by muse, mutect2, varscan2
- GJA3 | c.804C>T p.F268= | Silent (SNP) | VAF 258/605 reads (43%) | called by muse, mutect2, varscan2
- GMNC | c.852T>C p.A284= | Silent (SNP) | VAF 181/473 reads (38%) | called by muse, mutect2, varscan2
- GOLGA8S | c.1245C>T p.L415= | Silent (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- GRID2 | c.777C>T p.I259= | Silent (SNP) | VAF 139/316 reads (44%) | catalogued as COSV56184384; called by muse, mutect2, varscan2
- GRID2 | c.2238G>A p.L746= | Silent (SNP) | VAF 154/351 reads (44%) | called by muse, mutect2, varscan2
- GRIN2D | c.1719C>T p.S573= | Silent (SNP) | VAF 133/333 reads (40%) | called by muse, mutect2, varscan2
- GRM6 | c.660C>T p.A220= | Silent (SNP) | VAF 305/564 reads (54%) | called by muse, mutect2, varscan2
- GSTM2 | c.600G>A p.R200= | Silent (SNP) | VAF 114/354 reads (32%) | catalogued as COSV99860040; called by muse, mutect2, varscan2
- GUCY2D | c.1197G>A p.E399= | Silent (SNP) | VAF 271/616 reads (44%) | called by muse, mutect2, varscan2
- H2BW1 | c.228C>T p.C76= | Silent (SNP) | VAF 225/269 reads (84%) | called by muse, mutect2, varscan2
- HEATR1 | c.4572C>T p.L1524= | Silent (SNP) | VAF 115/266 reads (43%) | catalogued as COSV63982082; called by muse, mutect2, varscan2
- HNF1A | c.774C>T p.L258= | Silent (SNP) | VAF 213/507 reads (42%) | catalogued as rs756497242, COSV99983093; called by muse, mutect2, varscan2
- HOOK2 | c.1227G>A p.A409= | Silent (SNP) | VAF 181/467 reads (39%) | catalogued as rs754469382, COSV53402444, COSV53403522; called by muse, mutect2, varscan2
- HTR4 | c.1101C>T p.F367= | Silent (SNP) | VAF 293/355 reads (83%) | called by muse, mutect2, varscan2
- HUWE1 | c.2868C>T p.T956= | Silent (SNP) | VAF 134/157 reads (85%) | catalogued as rs1220092446; called by muse, mutect2, varscan2
- IGHV1-18 | c.93G>A p.K31= | Silent (SNP) | VAF 198/500 reads (40%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.22C>T p.L8= | Silent (SNP) | VAF 157/456 reads (34%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.21C>T p.L7= | Silent (SNP) | VAF 157/456 reads (34%) | called by muse, mutect2, varscan2
- ILVBL | c.795C>T p.I265= | Silent (SNP) | VAF 87/252 reads (35%) | catalogued as rs773156514; called by muse, mutect2, varscan2
- INAVA | c.1683C>T p.S561= | Silent (SNP) | VAF 37/364 reads (10%) | called by muse, mutect2, varscan2
- IRF2 | c.9G>C p.V3= | Silent (SNP) | VAF 122/302 reads (40%) | called by muse, mutect2, varscan2
- IRF2BPL | c.834C>T p.A278= | Silent (SNP) | VAF 157/393 reads (40%) | catalogued as rs1438533442; called by muse, mutect2, varscan2
- IRS2 | c.1731C>T p.S577= | Silent (SNP) | VAF 274/660 reads (42%) | called by muse, mutect2, varscan2
- ITGB4 | c.3435C>T p.F1145= | Silent (SNP) | VAF 161/431 reads (37%) | called by muse, mutect2, varscan2
- JAML | c.874C>T p.L292= (on ENST00000356289 / NM_001098526.2; = p.L282= on NM_153206.3) | Silent (SNP) | VAF 134/208 reads (64%) | catalogued as COSV52629811; called by muse, mutect2, varscan2
- KBTBD13 | c.924C>T p.F308= | Silent (SNP) | VAF 218/549 reads (40%) | catalogued as rs886051335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK18 | c.63C>T p.F21= | Silent (SNP) | VAF 377/449 reads (84%) | catalogued as rs1564988725, COSV100571965; called by muse, mutect2, varscan2
- KCNK6 | c.744C>T p.A248= | Silent (SNP) | VAF 139/373 reads (37%) | called by muse, mutect2, varscan2
- KCNU1 | c.681G>A p.L227= | Silent (SNP) | VAF 105/166 reads (63%) | called by muse, varscan2
- KIF1A | c.3006C>T p.F1002= | Silent (SNP) | VAF 165/477 reads (35%) | catalogued as COSV57491998; called by muse, mutect2, varscan2
- KIF5C | c.1653G>A p.L551= | Silent (SNP) | VAF 232/584 reads (40%) | called by muse, mutect2, varscan2
- KRTAP10-3 | c.591C>T p.L197= | Silent (SNP) | VAF 230/576 reads (40%) | catalogued as rs1555920184, COSV59979635; called by muse, mutect2, varscan2
- KRTAP10-5 | c.114C>T p.T38= | Silent (SNP) | VAF 286/748 reads (38%) | called by muse, mutect2
- LAMC2 | c.1521A>G p.E507= | Silent (SNP) | VAF 164/582 reads (28%) | called by muse, mutect2, varscan2
- LRFN2 | c.1272G>A p.R424= | Silent (SNP) | VAF 162/435 reads (37%) | catalogued as COSV100599986; called by muse, mutect2, varscan2
- LRIT1 | c.1047G>A p.P349= | Silent (SNP) | VAF 375/464 reads (81%) | catalogued as rs560573358, COSV100928063; called by muse, mutect2, varscan2
- LY9 | c.174C>T p.I58= | Silent (SNP) | VAF 137/511 reads (27%) | catalogued as COSV99627634; called by muse, mutect2, varscan2
- MARCHF9 | c.270C>T p.G90= | Silent (SNP) | VAF 204/497 reads (41%) | called by muse, mutect2, varscan2
- MBD3L3 | c.213G>A p.Q71= | Silent (SNP) | VAF 27/66 reads (41%) | called by mutect2, varscan2
- MEMO1 | c.90T>C p.G30= | Silent (SNP) | VAF 118/332 reads (36%) | called by muse, mutect2, varscan2
- MGAM2 | c.1665G>A p.R555= | Silent (SNP) | VAF 419/617 reads (68%) | called by muse, mutect2, varscan2
- MPPED1 | c.945C>T p.P315= | Silent (SNP) | VAF 144/401 reads (36%) | called by muse, mutect2, varscan2
- MTCH1 | c.510G>A p.K170= | Silent (SNP) | VAF 131/308 reads (43%) | catalogued as rs749656872; called by muse, mutect2, varscan2
- MUC16 | c.29784C>T p.S9928= | Silent (SNP) | VAF 182/402 reads (45%) | catalogued as COSV67474976; called by muse, mutect2
- MUC16 | c.25530C>T p.L8510= | Silent (SNP) | VAF 138/396 reads (35%) | called by muse, mutect2, varscan2
- MUC16 | c.15909G>A p.Q5303= | Silent (SNP) | VAF 212/511 reads (41%) | catalogued as COSV67481246; called by muse, mutect2, varscan2
- MYH8 | c.2619G>A p.R873= | Silent (SNP) | VAF 165/393 reads (42%) | catalogued as COSV67970772; called by muse, mutect2, varscan2
- MYPN | c.1719C>T p.P573= | Silent (SNP) | VAF 244/557 reads (44%) | catalogued as rs201279829, COSV100590230; called by muse, mutect2, varscan2
- NCKAP1L | c.387G>A p.R129= | Silent (SNP) | VAF 102/252 reads (40%) | catalogued as rs1020066912; called by muse, mutect2, varscan2
- NEBL | c.2067G>A p.K689= | Silent (SNP) | VAF 102/295 reads (35%) | called by muse, mutect2, varscan2
- NEXMIF | c.2248T>C p.L750= | Silent (SNP) | VAF 194/244 reads (80%) | called by muse, mutect2, varscan2
- NFXL1 | c.108G>A p.G36= | Silent (SNP) | VAF 225/536 reads (42%) | called by muse, mutect2, varscan2
- NUP160 | c.1113C>T p.F371= | Silent (SNP) | VAF 115/271 reads (42%) | catalogued as COSV65853919; called by muse, mutect2, varscan2
- OAS3 | c.3030C>T p.I1010= | Silent (SNP) | VAF 184/398 reads (46%) | called by muse, mutect2, varscan2
- OR10P1 | c.915G>A p.L305= | Silent (SNP) | VAF 151/357 reads (42%) | called by muse, mutect2, varscan2
- OR10X1 | c.579C>T p.F193= | Silent (SNP) | VAF 142/547 reads (26%) | called by muse, mutect2, varscan2
- OR11H4 | c.168C>T p.I56= | Silent (SNP) | VAF 163/430 reads (38%) | catalogued as COSV59559685; called by muse, mutect2, varscan2
- OR14K1 | c.870G>A p.L290= | Silent (SNP) | VAF 128/342 reads (37%) | catalogued as COSV99315472; called by muse, mutect2, varscan2
- OR2A12 | c.888G>A p.V296= | Silent (SNP) | VAF 125/566 reads (22%) | catalogued as rs758886665, COSV68821114; called by muse, mutect2, varscan2
- OR2G2 | c.336C>T p.S112= | Silent (SNP) | VAF 190/445 reads (43%) | catalogued as rs1336999469; called by muse, mutect2, varscan2
- OR2L2 | c.253C>T p.L85= | Silent (SNP) | VAF 122/303 reads (40%) | catalogued as rs1238657536, COSV63552739, COSV63557390; called by muse, mutect2, varscan2
- OR4C15 | c.603C>T p.A201= (on ENST00000314644; = p.A147= on NM_001001920.2) | Silent (SNP) | VAF 182/437 reads (42%) | called by muse, mutect2, varscan2
- OR52R1 | c.504G>A p.R168= | Silent (SNP) | VAF 199/492 reads (40%) | called by muse, mutect2, varscan2
- OR5D13 | c.357G>A p.A119= | Silent (SNP) | VAF 174/390 reads (45%) | catalogued as rs762902210; called by muse, mutect2, varscan2
- OR5H15 | c.705G>A p.R235= | Silent (SNP) | VAF 108/269 reads (40%) | catalogued as COSV62949403; called by muse, mutect2, varscan2
- OR7D2 | c.672C>T p.S224= | Silent (SNP) | VAF 148/409 reads (36%) | called by muse, mutect2, varscan2
- P3H2 | c.1356C>T p.F452= | Silent (SNP) | VAF 88/260 reads (34%) | catalogued as rs267599731, COSV60021707; called by muse, mutect2, varscan2
- P4HTM | c.759C>T p.D253= | Silent (SNP) | VAF 119/342 reads (35%) | called by muse, mutect2, varscan2
- PCDH15 | c.1029G>A p.R343= | Silent (SNP) | VAF 80/244 reads (33%) | catalogued as COSV57386419; called by muse, mutect2, varscan2
- PCDHB9 | c.339C>T p.P113= | Silent (SNP) | VAF 277/374 reads (74%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.900G>A p.L300= | Silent (SNP) | VAF 190/490 reads (39%) | called by muse, mutect2, varscan2
- PI4KA | c.5784C>T p.S1928= | Silent (SNP) | VAF 103/606 reads (17%) | catalogued as rs1434293899; called by muse, mutect2, varscan2
- PIEZO2 | c.5850C>T p.F1950= | Silent (SNP) | VAF 231/528 reads (44%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4443C>T p.V1481= | Silent (SNP) | VAF 148/534 reads (28%) | called by muse, mutect2, varscan2
- POTEI | c.2430G>A p.L810= | Silent (SNP) | VAF 240/641 reads (37%) | catalogued as rs1558877781; called by muse, mutect2, varscan2
- POU5F1B | c.1029C>G p.V343= | Silent (SNP) | VAF 188/545 reads (34%) | called by muse, mutect2, varscan2
- PRAM1 | c.39G>A p.Q13= | Silent (SNP) | VAF 118/314 reads (38%) | catalogued as COSV99725534; called by muse, mutect2, varscan2
- PRAMEF11 | c.471C>T p.L157= | Silent (SNP) | VAF 257/638 reads (40%) | called by muse, mutect2, varscan2
- PRUNE1 | c.93C>T p.S31= | Silent (SNP) | VAF 115/411 reads (28%) | catalogued as rs780609846; called by muse, mutect2, varscan2
- PTK7 | c.732C>T p.F244= | Silent (SNP) | VAF 187/450 reads (42%) | catalogued as COSV57851602; called by muse, mutect2, varscan2
- PTPN4 | c.1915C>T p.L639= | Silent (SNP) | VAF 166/409 reads (41%) | called by muse, mutect2, varscan2
- PTPRT | c.3465G>A p.E1155= | Silent (SNP) | VAF 195/430 reads (45%) | called by muse, mutect2, varscan2
- PTTG2 | c.564C>T p.D188= | Silent (SNP) | VAF 130/346 reads (38%) | called by muse, mutect2, varscan2
- PXYLP1 | c.210C>T p.I70= | Silent (SNP) | VAF 139/355 reads (39%) | called by muse, mutect2, varscan2
- RABEP1 | c.447C>T p.S149= | Silent (SNP) | VAF 144/364 reads (40%) | catalogued as rs758572176, COSV99336264; called by muse, varscan2
- RANBP17 | c.3153C>T p.S1051= | Silent (SNP) | VAF 98/329 reads (30%) | catalogued as rs766057211, COSV101206186; called by muse, mutect2, varscan2
- RAP1GAP | c.147C>T p.P49= | Silent (SNP) | VAF 162/355 reads (46%) | catalogued as rs1378921105; called by muse, mutect2, varscan2
- RASGEF1C | c.924C>T p.S308= | Silent (SNP) | VAF 319/544 reads (59%) | called by muse, mutect2, varscan2
- RASSF6 | c.132C>T p.I44= (on ENST00000342081 / NM_201431.2; = p.I12= on NM_177532.5) | Silent (SNP) | VAF 111/274 reads (41%) | called by muse, mutect2, varscan2
- REELD1 | c.57C>T p.S19= | Silent (SNP) | VAF 164/378 reads (43%) | called by muse, mutect2, varscan2
- REXO1 | c.966C>T p.P322= | Silent (SNP) | VAF 256/612 reads (42%) | catalogued as rs766603106; called by muse, mutect2, varscan2
- RFPL4A | c.657C>T p.F219= | Silent (SNP) | VAF 176/936 reads (19%) | catalogued as rs1198066961, COSV70455068; called by muse, varscan2
- RFPL4A | c.658C>T p.L220= | Silent (SNP) | VAF 176/938 reads (19%) | called by muse, varscan2
- RNASE13 | c.30C>T p.F10= | Silent (SNP) | VAF 176/402 reads (44%) | catalogued as COSV58794280; called by muse, mutect2
- RPL3L | c.939C>T p.S313= | Silent (SNP) | VAF 133/341 reads (39%) | called by muse, mutect2, varscan2
- RUNX2 | c.1464C>T p.A488= | Silent (SNP) | VAF 244/617 reads (40%) | called by muse, mutect2, varscan2
- SACS | c.4032C>T p.D1344= | Silent (SNP) | VAF 136/335 reads (41%) | called by muse, mutect2, varscan2
- SAXO1 | c.885C>T p.V295= | Silent (SNP) | VAF 222/299 reads (74%) | catalogued as rs1432551683; called by muse, mutect2, varscan2
- SCN2A | c.1755G>A p.K585= | Silent (SNP) | VAF 187/465 reads (40%) | called by muse, mutect2, varscan2
- SCN9A | c.4803G>C p.T1601= (on ENST00000303354; = p.T1590= on NM_002977.3) | Silent (SNP) | VAF 123/333 reads (37%) | catalogued as COSV100312791; called by muse, mutect2, varscan2
- SCN9A | c.3546G>A p.R1182= (on ENST00000303354; = p.R1171= on NM_002977.3) | Silent (SNP) | VAF 144/443 reads (33%) | catalogued as COSV57600088; called by muse, mutect2, varscan2
- SEC14L1 | c.2133C>T p.S711= | Silent (SNP) | VAF 139/351 reads (40%) | called by muse, mutect2, varscan2
- SERPINB11 | c.435G>A p.T145= | Silent (SNP) | VAF 116/382 reads (30%) | catalogued as rs367579501; called by muse, mutect2, varscan2
- SERPINB11 | c.552C>T p.F184= | Silent (SNP) | VAF 202/510 reads (40%) | catalogued as COSV66956906, COSV66956940; called by muse, mutect2
- SERPINB3 | c.1131G>A p.K377= | Silent (SNP) | VAF 132/350 reads (38%) | called by muse, mutect2, varscan2
- SH3TC1 | c.789C>T p.S263= | Silent (SNP) | VAF 298/669 reads (45%) | catalogued as rs200153598; called by muse, mutect2, varscan2
- SHISA8 | c.303C>G p.G101= (on ENST00000457093; = p.G134= on NM_001207020.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 244/625 reads (39%) | called by muse, mutect2, varscan2
- SHOX | c.312G>A p.V104= | Silent (SNP) | VAF 183/475 reads (39%) | catalogued as COSV61860574; called by muse, mutect2, varscan2
- SLC2A9 | c.207C>T p.F69= | Silent (SNP) | VAF 151/419 reads (36%) | catalogued as rs759350686; called by muse, mutect2, varscan2
- SLC6A2 | c.1455C>T p.V485= | Silent (SNP) | VAF 123/336 reads (37%) | called by muse, mutect2, varscan2
- SLCO2A1 | c.222C>T p.S74= | Silent (SNP) | VAF 116/292 reads (40%) | called by muse, mutect2, varscan2
- SMLR1 | c.51G>A p.R17= | Silent (SNP) | VAF 166/226 reads (73%) | catalogued as rs1185330683, COSV73407266; called by muse, mutect2, varscan2
- SPATC1 | c.159C>T p.F53= | Silent (SNP) | VAF 174/433 reads (40%) | called by muse, mutect2, varscan2
- SPEM2 | c.867C>T p.N289= | Silent (SNP) | VAF 170/509 reads (33%) | called by muse, varscan2
- SPOCD1 | c.2208C>T p.T736= | Silent (SNP) | VAF 179/416 reads (43%) | called by muse, mutect2, varscan2
- SREBF1 | c.435G>T p.L145= | Silent (SNP) | VAF 277/639 reads (43%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2697C>T p.I899= | Silent (SNP) | VAF 209/518 reads (40%) | catalogued as rs1232063428; called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | c.897C>T p.A299= | Silent (SNP) | VAF 132/344 reads (38%) | called by muse, mutect2, varscan2
- STS | c.1071G>A p.G357= | Silent (SNP) | VAF 97/117 reads (83%) | called by muse, mutect2, varscan2
- SV2C | c.1017C>T p.F339= | Silent (SNP) | VAF 129/480 reads (27%) | called by muse, mutect2, varscan2
- TAS2R41 | c.420C>T p.I140= | Silent (SNP) | VAF 162/720 reads (23%) | called by muse, mutect2, varscan2
- TBC1D24 | c.285C>T p.F95= | Silent (SNP) | VAF 208/522 reads (40%) | catalogued as rs774354974; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TMOD2 | c.297C>T p.I99= | Silent (SNP) | VAF 59/151 reads (39%) | catalogued as COSV51044172; called by muse, mutect2, varscan2
- TNN | c.600G>A p.P200= | Silent (SNP) | VAF 260/652 reads (40%) | catalogued as rs763252970; called by muse, mutect2, varscan2
- TPO | c.1590C>T p.L530= | Silent (SNP) | VAF 141/347 reads (41%) | called by muse, mutect2, varscan2
- TRAK1 | c.237C>T p.A79= | Silent (SNP) | VAF 168/368 reads (46%) | called by muse, mutect2, varscan2
- TTC21A | c.1437C>T p.I479= | Silent (SNP) | VAF 137/340 reads (40%) | catalogued as rs1436236250, COSV100087778, COSV57184901; called by muse, mutect2, varscan2
- TTN | c.4851C>T p.I1617= (on ENST00000591111; = p.I1571= on NM_003319.4) | Silent (SNP) | VAF 179/379 reads (47%) | catalogued as rs756286153, COSV59911162; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBGCP3 | c.1401G>A p.R467= | Silent (SNP) | VAF 139/325 reads (43%) | catalogued as rs1193149591; called by muse, mutect2, varscan2
- TXN | c.162C>T p.F54= | Silent (SNP) | VAF 113/280 reads (40%) | called by muse, mutect2, varscan2
- UEVLD | c.246C>T p.F82= | Silent (SNP) | VAF 136/331 reads (41%) | catalogued as rs140539629; called by muse, mutect2, varscan2
- UGT2A1 | c.1518C>T p.V506= | Silent (SNP) | VAF 123/333 reads (37%) | catalogued as COSV99683927; called by muse, mutect2, varscan2
- USP21 | c.906C>G p.A302= | Silent (SNP) | VAF 278/512 reads (54%) | called by muse, mutect2
- VWF | c.4518G>A p.S1506= | Silent (SNP) | VAF 191/429 reads (45%) | catalogued as rs146928422; called by muse, mutect2, varscan2
- WASHC2A | c.3384C>T p.D1128= | Silent (SNP) | VAF 241/641 reads (38%) | called by muse, mutect2, varscan2
- WASL | c.297A>C p.V99= | Silent (SNP) | VAF 137/308 reads (44%) | called by muse, mutect2, varscan2
- WDFY2 | c.804C>T p.V268= | Silent (SNP) | VAF 126/300 reads (42%) | called by muse, mutect2, varscan2
- WDR81 | c.5544C>T p.D1848= (on ENST00000409644 / NM_001163809.2; = p.D797= on NM_152348.4) | Silent (SNP) | VAF 145/353 reads (41%) | called by muse, mutect2, varscan2
- ZBTB16 | c.171G>A p.K57= | Silent (SNP) | VAF 181/265 reads (68%) | catalogued as rs1257026641; called by muse, mutect2, varscan2
- ZBTB41 | c.1248A>G p.E416= | Silent (SNP) | VAF 176/431 reads (41%) | called by muse, mutect2, varscan2
- ZDBF2 | c.6141G>A p.R2047= | Silent (SNP) | VAF 127/291 reads (44%) | called by muse, mutect2, varscan2
- ZEB2 | c.1905C>T p.L635= | Silent (SNP) | VAF 154/399 reads (39%) | catalogued as rs1188397889; called by muse, mutect2, varscan2
- ZFP28 | c.1110G>A p.K370= | Silent (SNP) | VAF 121/319 reads (38%) | catalogued as rs1434794437; called by muse, mutect2, varscan2
- ZFYVE28 | c.492C>T p.F164= | Silent (SNP) | VAF 147/362 reads (41%) | catalogued as rs760074037, COSV52112854, COSV52116935; called by muse, mutect2, varscan2
- ZNF23 | c.720C>T p.I240= | Silent (SNP) | VAF 178/431 reads (41%) | catalogued as rs1283701603, COSV100612113; called by muse, mutect2, varscan2
- ZNF385A | c.57G>A p.P19= | Silent (SNP) | VAF 252/585 reads (43%) | catalogued as rs778845381, COSV61492773; called by muse, mutect2, varscan2
- ZNF385C | c.297C>T p.P99= | Silent (SNP) | VAF 249/569 reads (44%) | called by muse, mutect2, varscan2
- ZNF469 | c.381G>T p.S127= | Silent (SNP) | VAF 250/336 reads (74%) | called by muse, mutect2, varscan2
- ZNF512 | c.1404C>T p.F468= | Silent (SNP) | VAF 89/265 reads (34%) | catalogued as rs765557795, COSV60966558; called by muse, mutect2, varscan2
- ZNF699 | c.1461C>T p.S487= | Silent (SNP) | VAF 144/385 reads (37%) | called by muse, mutect2, varscan2
- ANGEL1 | c.1381-30C>T | Intron (SNP) | VAF 234/542 reads (43%) | catalogued as rs1237711221; called by muse, mutect2, varscan2
- APAF1 | c.*2665C>T | 3'UTR (SNP) | VAF 80/195 reads (41%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915986 G>A | 5'Flank (SNP) | VAF 190/492 reads (39%) | called by muse, mutect2
- ATXN8OS | n.499+1378C>T | Intron (SNP) | VAF 33/151 reads (22%) | called by muse, mutect2, varscan2
- BORCS5 | chr12:12357038 C>T | 5'Flank (SNP) | VAF 103/228 reads (45%) | called by muse, mutect2, varscan2
- C4orf50 | c.-343G>A | 5'UTR (SNP) | VAF 140/342 reads (41%) | called by muse, mutect2, varscan2
- C8orf34 | c.1549+3329C>T | Intron (SNP) | VAF 118/334 reads (35%) | called by muse, mutect2, varscan2
- CCDC102A | c.*304C>T | 3'UTR (SNP) | VAF 101/280 reads (36%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2688C>T | Intron (SNP) | VAF 208/490 reads (42%) | called by muse, mutect2, varscan2
- DCHS2 | n.3855G>A | RNA (SNP) | VAF 113/302 reads (37%) | catalogued as rs1309994602, COSV61771238; called by muse, mutect2, varscan2
- DCHS2 | n.3119C>T | RNA (SNP) | VAF 197/455 reads (43%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65784C>T | Intron (SNP) | VAF 212/312 reads (68%) | catalogued as rs1272117491, COSV54644679; called by muse, mutect2, varscan2
- DMRTC2 | c.816+66G>A | Intron (SNP) | VAF 218/522 reads (42%) | catalogued as COSV54185646; called by muse, mutect2, varscan2
- DNAH14 | c.5584+5690T>A | Intron (SNP) | VAF 94/253 reads (37%) | called by muse, mutect2, varscan2
- FSIP2 | chr2:185738721 C>T | 5'Flank (SNP) | VAF 211/540 reads (39%) | called by muse, mutect2, varscan2
- HBS1L | c.430+2645C>T | Intron (SNP) | VAF 166/214 reads (78%) | called by muse, mutect2, varscan2
- HELLPAR | n.199233G>A | RNA (SNP) | VAF 71/204 reads (35%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+2161G>A | Intron (SNP) | VAF 174/462 reads (38%) | catalogued as rs1274945833, COSV55173773; called by muse, mutect2, varscan2
- IGFN1 | c.1242-625G>A | Intron (SNP) | VAF 220/518 reads (42%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-7619G>A | Intron (SNP) | VAF 112/305 reads (37%) | called by muse, mutect2, varscan2
- KCTD1 | c.-15-46893G>T | Intron (SNP) | VAF 206/498 reads (41%) | called by muse, mutect2, varscan2
- LCK | c.965-65G>A | Intron (SNP) | VAF 151/392 reads (39%) | called by muse, mutect2, varscan2
- LSP1 | c.54-13200G>A | Intron (SNP) | VAF 186/497 reads (37%) | called by muse, mutect2, varscan2
- LTN1 | chr21:28992924 C>T | 5'Flank (SNP) | VAF 108/279 reads (39%) | catalogued as rs1361978205, COSV57478291; called by muse, mutect2, varscan2
- MACF1 | c.15832-9588C>T | Intron (SNP) | VAF 193/481 reads (40%) | catalogued as rs1243918155; called by muse, mutect2, varscan2
- MARCHF1 | c.242+737G>A | Intron (SNP) | VAF 134/302 reads (44%) | called by muse, mutect2, varscan2
- MYL12B | c.-1C>T | 5'UTR (SNP) | VAF 129/304 reads (42%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109794C>T | Intron (SNP) | VAF 175/481 reads (36%) | catalogued as rs750429738; called by muse, varscan2
- OR2T2 | chr1:248441742 C>T | 5'Flank (SNP) | VAF 155/856 reads (18%) | catalogued as rs747811000; called by muse, varscan2
- PRB3 | c.604+52C>A | Intron (SNP) | VAF 67/406 reads (17%) | called by muse, varscan2
- PRDM11 | chr11:45226176 C>T | 3'Flank (SNP) | VAF 212/481 reads (44%) | called by muse, mutect2, varscan2
- PRORY | n.201C>T | RNA (SNP) | VAF 192/226 reads (85%) | called by muse, mutect2, varscan2
- REXO1L1P | n.1405C>T | RNA (SNP) | VAF 38/626 reads (6%) | called by muse, mutect2
- SATL1 | c.-551C>T | 5'UTR (SNP) | VAF 127/177 reads (72%) | called by muse, mutect2, varscan2
- SIRPB1 | c.*460C>T | 3'UTR (SNP) | VAF 112/326 reads (34%) | called by muse, mutect2, varscan2
- SIRPB1 | c.*459C>T | 3'UTR (SNP) | VAF 111/324 reads (34%) | called by muse, mutect2, varscan2
- SPDYE16 | chr7:76541334 C>T | 5'Flank (SNP) | VAF 351/612 reads (57%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185958 C>T | 5'Flank (SNP) | VAF 166/242 reads (69%) | catalogued as rs1187663897, COSV59440447; called by muse, mutect2, varscan2
- TTN | c.10360+3063C>T | Intron (SNP) | VAF 180/436 reads (41%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-3003C>T | Intron (SNP) | VAF 135/342 reads (39%) | catalogued as rs1285963153; called by muse, mutect2, varscan2
- ZNF720 | c.361+228C>T | Intron (SNP) | VAF 85/220 reads (39%) | called by muse, mutect2, varscan2
- ZNF8 | chr19:58277231 G>A | 5'Flank (SNP) | VAF 133/307 reads (43%) | called by muse, mutect2, varscan2
